Somatic mutation profile of tumor specimen C3N-01824-03 (aliquot CPT0097170006) from CPTAC case C3N-01824, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 58.3 years (21,302 days).
Specimen C3N-01824-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7284e24-0b4d-44c0-9b91-da7556142cf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01824-71 (Blood Derived Normal), aliquot CPT0097190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/193001b4-a53e-450c-8deb-3232dc551bf6

The open-access MAF lists 799 somatic variants for this specimen: 523 protein-altering or splice-affecting, 254 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 467, Silent 254, Nonsense Mutation 40, Intron 17, Splice Site 6, Splice Region 4, Frame Shift Del 4, 5'Flank 2, 3'Flank 1, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (750 of 799; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 143/381 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLCN2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 74/485 reads (15%) | catalogued as rs863225250, COSV99658572; ClinVar: pathogenic; called by muse, mutect2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 26/421 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2
- MYBPC3 | c.3294G>A p.W1098* | Nonsense Mutation (SNP) | VAF 76/353 reads (22%) | catalogued as rs767039057, CM106119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 81/329 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520004, COSV52676908, COSV52856938, COSV52866969, COSV53036902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1244G>A p.G415E (on ENST00000373993 / NM_138932.2; = p.G407E on NM_014576.4) | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.157); catalogued as COSV50966387; called by muse, mutect2, varscan2
- ABCA13 | c.13798-1G>A p.X4600_splice | Splice Site (SNP) | VAF 100/225 reads (44%) | catalogued as COSV68948660; called by muse, mutect2, varscan2
- ABCA2 | c.7040T>C p.V2347A (on ENST00000614293; = p.V2317A on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/500 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1245551598; called by muse, mutect2, varscan2
- ABCC6 | c.3904G>T p.G1302W | Missense Mutation (SNP) | VAF 132/552 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as CM014494; called by muse, mutect2, varscan2
- ABCC9 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 103/354 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.449); catalogued as COSV53976173; called by muse, mutect2, varscan2
- ABRA | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 76/624 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs891290416; called by muse, mutect2, varscan2
- AC099489.1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs992372315; called by muse, mutect2, varscan2
- ACE | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 87/358 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs989500910, COSV52004988; called by muse, mutect2, varscan2
- ACSM1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 59/231 reads (26%) | catalogued as rs199570072, COSV54637144; called by muse, mutect2, varscan2
- ADH1C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 146/614 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV72463418; called by muse, mutect2, varscan2
- ADIRF | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs376853320; called by muse, mutect2, varscan2
- AGBL5 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs745987547, COSV59937276; called by muse, mutect2, varscan2
- ALG12 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 120/505 reads (24%) | PolyPhen benign (0.397); catalogued as rs1275016834; called by muse, mutect2, varscan2
- ALS2CL | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 151/647 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV59673070; called by muse, varscan2
- AMIGO1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 158/568 reads (28%) | catalogued as COSV63990320; called by muse, mutect2, varscan2
- AMPD1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs587779379, COSV62416273, COSV62417108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD35 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 103/431 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62911322; called by muse, mutect2, varscan2
- ANO1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 196/711 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs764375332; called by muse, mutect2, varscan2
- AOX1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs746941935; called by muse, mutect2, varscan2
- ARGLU1 | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 315/603 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV62271750; called by muse, mutect2, varscan2
- ARHGAP12 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV60965905; called by muse, mutect2, varscan2
- ARHGEF6 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99166409; called by muse, mutect2, varscan2
- ARSF | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 123/258 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764292225, COSV63839301; called by muse, mutect2, varscan2
- ASXL1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370054224; called by muse, mutect2, varscan2
- ASXL3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1411906940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN1L | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 133/517 reads (26%) | catalogued as rs1197781166; called by muse, mutect2, varscan2
- AUTS2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 48/1065 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as rs1184884717, COSV61396619; called by muse, mutect2
- BSG | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.915); catalogued as rs1241844764, COSV61076919; called by muse, mutect2, varscan2
- C1QTNF4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 160/595 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.28); catalogued as rs767479537; called by muse, mutect2, varscan2
- C3 | c.4619G>A p.G1540E | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs771087404; called by muse, mutect2, varscan2
- C3 | c.2804G>A p.G935E | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55572718; called by muse, mutect2
- C7 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 270/576 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472311; called by muse, mutect2, varscan2
- CACNA1E | c.3423G>A p.P1141= | Splice Region (SNP) | VAF 65/280 reads (23%) | catalogued as COSV100703915; called by muse, mutect2, varscan2
- CACNA1I | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 118/405 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs1301627790; called by muse, mutect2, varscan2
- CAND2 | c.1033G>A p.D345N (on ENST00000456430 / NM_001162499.2; = p.D252N on NM_012298.3) | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs757397927, COSV55992875; called by muse, mutect2, varscan2
- CAPN1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs375107477; called by muse, mutect2, varscan2
- CAPZA3 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 136/568 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577490193, COSV99856891; called by muse, mutect2, varscan2
- CCDC144A | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60698178; called by muse, varscan2
- CCDC152 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62792327; called by muse, mutect2, varscan2
- CCDC166 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 386/913 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1554616695; called by muse, mutect2, varscan2
- CCDC39 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99870093; called by muse, mutect2, varscan2
- CCDC54 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 112/404 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as COSV99660348; called by muse, mutect2, varscan2
- CCKAR | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 125/576 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55160299; called by muse, mutect2, varscan2
- CD300E | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 94/417 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.151); catalogued as COSV60789874; called by muse, mutect2, varscan2
- CDC25C | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 33/364 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV60398349; called by muse, mutect2
- CDH18 | c.105A>C p.R35S | Missense Mutation (SNP) | VAF 338/707 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56945811; called by muse, mutect2, varscan2
- CDH5 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 151/530 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs767473826; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 157/408 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CFAP20DC | c.664C>T p.R222C (on ENST00000482387 / NM_001351530.2; = p.R97C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/445 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs773017513, COSV55918449; called by muse, mutect2, varscan2
- CIB3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs767528190, COSV54165469, COSV99521974; called by muse, mutect2, varscan2
- CLMP | c.1085T>C p.M362T | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs948395589; called by muse, mutect2, varscan2
- CNDP1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs202206682; called by muse, mutect2, varscan2
- COL11A2 | c.2324G>A p.G775E (on ENST00000341947 / NM_080680.3; = p.G668E on NM_080679.2) | Missense Mutation (SNP) | VAF 157/782 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495656; called by muse, mutect2, varscan2
- COL17A1 | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs758611661; called by muse, mutect2, varscan2
- COL1A1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 125/485 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV56804589; called by muse, mutect2, varscan2
- COL21A1 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 128/536 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs772334488; called by muse, mutect2, varscan2
- COL4A2 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 111/631 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100847464, COSV64628126; called by muse, mutect2, varscan2
- COL4A4 | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.021); catalogued as rs770315777, COSV61629272; called by muse, mutect2, varscan2
- COL4A5 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1569493681, COSV60357134; called by muse, mutect2, varscan2
- COL6A3 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 83/336 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs532388240; called by muse, mutect2, varscan2
- CRNKL1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 130/523 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs763086392, COSV55619227, COSV99844357; called by muse, mutect2, varscan2
- CYP2C8 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748167187, COSV64876214; called by muse, mutect2, varscan2
- DHX16 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 366/1020 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV99527658; called by muse, mutect2, varscan2
- DLGAP1 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs767953562; called by muse, mutect2, varscan2
- DNAH11 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60961037; called by muse, mutect2, varscan2
- DNAH12 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1207891177, COSV104418255; called by muse, mutect2
- DNAH17 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101103387; called by muse, mutect2, varscan2
- DNAH5 | c.9497G>A p.R3166K | Missense Mutation (SNP) | VAF 108/697 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV99446929; called by muse, mutect2, varscan2
- DNAH5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 74/569 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV54239692; called by muse, mutect2, varscan2
- DNAH9 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV52366634; called by muse, varscan2
- DNAH9 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV52340315; called by muse, varscan2
- DNAJC12 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs1390492394, COSV56548402; called by muse, mutect2, varscan2
- DOK6 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 115/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66928081; called by muse, mutect2, varscan2
- DPPA3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.049); catalogued as COSV61502894; called by muse, mutect2, varscan2
- DSG4 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV57395550; called by muse, mutect2, varscan2
- EFCAB13 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58948262; called by muse, mutect2, varscan2
- ENAH | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as COSV52868730; called by muse, mutect2, varscan2
- ENAM | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 153/584 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.248); catalogued as rs867796122, COSV68535183; called by muse, mutect2, varscan2
- EPHA7 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 187/401 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65168763; called by muse, mutect2, varscan2
- ERC2 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55673317; called by muse, mutect2, varscan2
- FAM170A | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373177857; called by muse, mutect2, varscan2
- FAM217A | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 156/444 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.053); catalogued as rs924517043; called by muse, mutect2, varscan2
- FBN3 | c.7345G>A p.E2449K | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777471590, COSV54457456; called by muse, mutect2
- FBXO43 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 123/540 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs769597754, COSV71053747, COSV71054194; called by muse, mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 106/469 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, varscan2
- FFAR1 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 197/708 reads (28%) | catalogued as rs374423505; called by muse, mutect2, varscan2
- FLG | c.8387G>A p.G2796E | Missense Mutation (SNP) | VAF 132/1103 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV64241999; called by muse, mutect2, varscan2
- FLRT2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1362116180, COSV100420545; called by muse, mutect2, varscan2
- GABRA2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV62917848; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GALE | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1245959586; called by muse, mutect2, varscan2
- GALNT6 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV62542626; called by muse, mutect2, varscan2
- GJB3 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961534236, COSV64904833; called by muse, varscan2
- GPR33 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 105/455 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767940921; called by muse, mutect2, varscan2
- GPRIN1 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 110/483 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV56139220; called by muse, mutect2, varscan2
- GRINA | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 96/430 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1203158723, COSV57592019; called by muse, mutect2, varscan2
- GSAP | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as rs1296449406, COSV99990336; called by muse, mutect2
- GUCY2F | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs779783238, COSV54299462; called by muse, mutect2, varscan2
- HABP2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 100/383 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); catalogued as COSV63638281; called by muse, mutect2, varscan2
- HDAC9 | c.11T>G p.M4R | Missense Mutation (SNP) | VAF 70/491 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1284593198; called by muse, mutect2, varscan2
- HEPHL1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 125/416 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1358867447; called by muse, mutect2, varscan2
- HNF1B | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 139/572 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374126219; ClinVar: uncertain significance; called by muse, varscan2
- IL1RL1 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as rs1475246537; called by muse, mutect2, varscan2
- INSYN2B | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 135/500 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs534161129, COSV99911494; called by muse, varscan2
- KCNA7 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 148/584 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV99078712; called by muse, mutect2
- KCNH6 | c.2333G>A p.G778E | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1040715870; called by muse, mutect2
- KCTD13 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 129/562 reads (23%) | catalogued as rs1328377309; called by muse, mutect2, varscan2
- KIF2B | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 125/471 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs904138536, COSV52134145, COSV99275155; called by muse, mutect2, varscan2
- KLF15 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99955066; called by muse, mutect2, varscan2
- KMT2A | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV63283926; called by muse, mutect2, varscan2
- KMT2B | c.3515G>C p.R1172P | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55859643; called by muse, mutect2, varscan2
- LNP1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767811020, COSV67347070; called by muse, mutect2, varscan2
- LRRC3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs865841768, COSV67520179, COSV67522722; called by muse, mutect2, varscan2
- LTBP1 | c.1418G>A p.G473E (on ENST00000404816 / NM_206943.4; = p.G147E on NM_000627.4) | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs745306877, COSV63181215; called by muse, mutect2, varscan2
- LY6G6D | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 164/602 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as COSV101010832; called by muse, mutect2, varscan2
- MAGEA11 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs782802430, COSV60758698; called by muse, mutect2, varscan2
- MAPKBP1 | c.2933G>A p.G978E (on ENST00000456763 / NM_001128608.2; = p.G972E on NM_014994.3) | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs750008902; called by muse, mutect2, varscan2
- MAST3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1235994502; called by muse, mutect2, varscan2
- MGAT4D | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421914709; called by muse, mutect2, varscan2
- MIA2 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1804860; called by muse, mutect2
- MINDY3 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 135/447 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99510445; called by muse, mutect2, varscan2
- MKKS | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 148/535 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1444144469; called by muse, mutect2, varscan2
- MLXIPL | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 196/478 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV57668202; called by muse, mutect2, varscan2
- MORC1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV51724672; called by muse, mutect2, varscan2
- MUC17 | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 114/574 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV60300816; called by muse, mutect2, varscan2
- MUC6 | c.3734C>T p.T1245I | Missense Mutation (SNP) | VAF 162/720 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1204003803, COSV70142298, COSV70143316; called by muse, varscan2
- MYO15A | c.7579G>A p.A2527T | Missense Mutation (SNP) | VAF 130/540 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52756124; called by muse, varscan2
- MYO18B | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs933991735; called by muse, mutect2, varscan2
- MYO1F | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 144/465 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1299092338; called by muse, mutect2, varscan2
- MYO5B | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV53215237; called by muse, mutect2, varscan2
- MYOCD | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1394360964, COSV58497819; called by muse, mutect2, varscan2
- NAP1L5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 132/468 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1263793444; called by muse, mutect2, varscan2
- NBEA | c.4663-1G>A p.X1555_splice | Splice Site (SNP) | VAF 65/353 reads (18%) | catalogued as COSV59818056; called by muse, mutect2, varscan2
- NDN | c.822A>T p.Q274H | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV59360304; called by muse, mutect2, varscan2
- NEB | c.10367G>A p.W3456* | Nonsense Mutation (SNP) | VAF 60/269 reads (22%) | catalogued as COSV51440549; called by muse, mutect2, varscan2
- NEURL4 | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100223169; called by muse, mutect2, varscan2
- NLGN4X | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 119/225 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323708; called by muse, mutect2, varscan2
- NLRP12 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 148/562 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV60754454; called by muse, mutect2, varscan2
- NLRP4 | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 102/425 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs967849267; called by muse, mutect2, varscan2
- NOL4 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV52355333; called by muse, mutect2, varscan2
- NOS1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 100/438 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1470536078, COSV57613018; called by muse, mutect2, varscan2
- OR1J4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 182/430 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61589744; called by muse, mutect2, varscan2
- OR2L3 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 95/454 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs202209437, COSV63455676; called by muse, mutect2, varscan2
- OR2T12 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 175/679 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs138674715; called by muse, mutect2, varscan2
- OR51A4 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 119/516 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100985199; called by muse, varscan2
- OR5D13 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs867480738, COSV100686785; called by muse, mutect2, varscan2
- OR8K1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 107/508 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); catalogued as rs772960419, COSV54401364; called by muse, mutect2, varscan2
- P2RX6 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 59/365 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1173940643; called by muse, mutect2, varscan2
- PABPC3 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 411/780 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV55804550; called by muse, mutect2, varscan2
- PADI4 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs774489770; called by muse, mutect2, varscan2
- PAPSS1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190978842, COSV54488263; called by muse, mutect2, varscan2
- PCBD1 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs754283743; called by muse, mutect2, varscan2
- PCBP3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1294527694; called by muse, mutect2, varscan2
- PCDH15 | c.4213C>T p.R1405C | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148046721, COSV100218567; called by muse, varscan2
- PCDHA10 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 187/374 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs912006741; called by muse, mutect2, varscan2
- PCK1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs141813623; called by muse, mutect2, varscan2
- PDE4DIP | c.3308G>A p.R1103K | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.313); catalogued as rs1553577318; called by muse, varscan2
- PDZD3 | c.1036G>A p.E346K (on ENST00000531114; = p.E266K on NM_024791.4) | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV52701893; called by muse, mutect2, varscan2
- PELI1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 120/472 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017072616; called by muse, mutect2, varscan2
- PELI1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 118/468 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62729310; called by muse, mutect2, varscan2
- PIK3R2 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs770193876; called by muse, mutect2, varscan2
- PLA2G4C | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs755393129; called by muse, mutect2, varscan2
- PLA2G4E | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1302138346, COSV68151867; called by muse, mutect2
- PLEKHG4B | c.2383G>A p.E795K (on ENST00000283426; = p.E1151K on NM_052909.5) | Missense Mutation (SNP) | VAF 108/768 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs1175297033; called by muse, mutect2, varscan2
- PLXNA4 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 94/508 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1241211048, COSV58122694; called by muse, mutect2, varscan2
- PLXNB1 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 134/515 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs761224080; called by muse, mutect2, varscan2
- POFUT1 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs752809888, COSV101003249; called by muse, mutect2, varscan2
- POLR2A | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 99/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746118363; called by muse, mutect2, varscan2
- PRDM1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 234/499 reads (47%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.929); catalogued as rs750485966; called by muse, mutect2, varscan2
- PRR29 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.415); catalogued as COSV99856916; called by muse, mutect2, varscan2
- PSG3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 100/460 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.52); catalogued as COSV100548877; called by mutect2, varscan2
- PTGES3L-AARSD1 | c.658C>T p.P220S (on ENST00000421990 / NM_001136042.2; = p.P202S on NM_025267.3) | Missense Mutation (SNP) | VAF 116/489 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.725); catalogued as COSV64181925; called by muse, mutect2, varscan2
- PTPN2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 87/322 reads (27%) | catalogued as COSV100518432; called by muse, mutect2, varscan2
- PTPRQ | c.5405G>A p.G1802E (on ENST00000616559; = p.G1760E on NM_001145026.2) | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57034742; called by muse, mutect2, varscan2
- RAD54L2 | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 129/566 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.992); catalogued as COSV56577726; called by muse, mutect2, varscan2
- RAD54L2 | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 126/560 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1326134041; called by muse, mutect2, varscan2
- RALBP1 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 150/617 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs1457796369; called by muse, mutect2, varscan2
- RASA3 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 103/608 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs751128700, COSV61864215; called by muse, mutect2, varscan2
- RBP4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753226964; called by muse, mutect2, varscan2
- RIMKLA | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as COSV101343495; called by muse, mutect2, varscan2
- RIMS2 | c.2563C>T p.H855Y (on ENST00000666250 / NM_001348490.2; = p.H663Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 190/494 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295663978, COSV51719862; called by muse, mutect2, varscan2
- RNF2 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 117/452 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV100835700; called by muse, mutect2, varscan2
- RYR2 | c.10342G>A p.E3448K | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.934); catalogued as COSV63671351; called by muse, mutect2
- RYR3 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 129/490 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370542262; called by muse, mutect2, varscan2
- SCN10A | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs767815241, COSV101479306; called by muse, mutect2, varscan2
- SCNN1D | c.535C>T p.P179S (on ENST00000338555; = p.P343S on NM_001130413.4) | Missense Mutation (SNP) | VAF 154/648 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1391452543; called by muse, mutect2, varscan2
- SCUBE2 | c.2318C>T p.S773F (on ENST00000649792 / NM_001367977.2; = p.S716F on NM_020974.3) | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58540817; called by muse, mutect2, varscan2
- SEZ6 | c.2857G>A p.G953R | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.127); catalogued as rs1443994023; called by muse, mutect2, varscan2
- SHD | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 148/539 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV101619071, COSV73378752; called by muse, mutect2, varscan2
- SIGLEC12 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs868615338, COSV52459250; called by muse, mutect2, varscan2
- SLC12A5 | c.866C>T p.S289F (on ENST00000454036 / NM_001134771.2; = p.S266F on NM_020708.5) | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54803097; called by muse, mutect2, varscan2
- SLC16A14 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 178/702 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as rs201868521, COSV54616755; called by muse, mutect2, varscan2
- SLC22A15 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV101047368; called by muse, mutect2, varscan2
- SLC2A14 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 124/405 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs375233021; called by muse, mutect2, varscan2
- SLC37A3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 120/534 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs200119569; called by muse, mutect2, varscan2
- SLC38A4 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs764640245, COSV56969554; called by muse, mutect2, varscan2
- SLC38A8 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 144/542 reads (27%) | catalogued as COSV55305409; called by muse, mutect2, varscan2
- SORL1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52760222; called by muse, mutect2, varscan2
- SORL1 | c.3238C>T p.R1080C | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs376993434; called by muse, mutect2, varscan2
- SOX17 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 312/769 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1219111000, COSV52024315; called by muse, mutect2, varscan2
- SOX6 | c.1967G>A p.G656E (on ENST00000528429 / NM_001145819.2; = p.G629E on NM_017508.3) | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57053405; called by muse, mutect2, varscan2
- SPAG17 | c.3715G>A p.G1239R | Missense Mutation (SNP) | VAF 122/450 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60455195; called by muse, mutect2, varscan2
- SPARCL1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 138/511 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56805321; called by muse, mutect2, varscan2
- SPTBN1 | c.6508C>T p.P2170S | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs202001000, COSV100442799; called by muse, mutect2, varscan2
- STAB2 | c.6497C>T p.P2166L | Missense Mutation (SNP) | VAF 112/457 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.11); catalogued as rs143368827, COSV101186387; called by muse, mutect2, varscan2
- STEAP1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 169/528 reads (32%) | catalogued as rs774074314, COSV51881399; called by muse, varscan2
- STRN | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55745851; called by muse, mutect2, varscan2
- TAS2R9 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 138/563 reads (25%) | catalogued as COSV53691152; called by muse, mutect2, varscan2
- TBC1D32 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV51549447; called by muse, mutect2, varscan2
- TCAIM | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs142277459; called by muse, mutect2, varscan2
- TDRD6 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 40/760 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60177831; called by muse, mutect2
- TMC4 | c.892G>A p.A298T (on ENST00000617472 / NM_001145303.3; = p.A292T on NM_144686.4) | Missense Mutation (SNP) | VAF 177/717 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1265458773; called by muse, mutect2, varscan2
- TMEM132C | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 100/398 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV70660896; called by muse, varscan2
- TMEM132D | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.648); catalogued as rs370621503; called by muse, mutect2, varscan2
- TNFRSF13B | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 140/521 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1350030808, BM1290773; called by muse, mutect2, varscan2
- TNXB | c.8779G>C p.G2927R (on ENST00000647633; = p.G2680R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 349/934 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64485348; called by muse, mutect2, varscan2
- TOR1AIP2 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 82/420 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV62625627; called by muse, mutect2, varscan2
- TP63 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.173); catalogued as rs1209841422, COSV53200694; called by muse, mutect2, varscan2
- TPBG | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 209/421 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV63882762; called by muse, mutect2, varscan2
- TRANK1 | c.4781C>T p.S1594F | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57145729; called by muse, mutect2, varscan2
- TRAV6 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 130/510 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.755); catalogued as rs981116475; called by muse, mutect2, varscan2
- TRBV24-1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs747642641; called by muse, mutect2, varscan2
- TRIM56 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 128/725 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as COSV100047166; called by muse, mutect2, varscan2
- TSPOAP1 | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 141/608 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as rs535567167; called by muse, mutect2, varscan2
- TTLL2 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 195/402 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as rs376630712; called by muse, mutect2
- TTN | c.50350G>A p.G16784R (on ENST00000591111; = p.G9360R on NM_003319.4) | Missense Mutation (SNP) | VAF 56/253 reads (22%) | PolyPhen benign (0.232); catalogued as COSV59920397; called by muse, mutect2, varscan2
- TTN | c.30580G>A p.E10194K (on ENST00000591111; = p.E9267K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/302 reads (21%) | PolyPhen benign (0); catalogued as rs1238948061, COSV59883774; called by muse, mutect2, varscan2
- TTN | c.6950G>T p.R2317L (on ENST00000591111; = p.R2271L on NM_003319.4) | Missense Mutation (SNP) | VAF 35/536 reads (7%) | PolyPhen probably damaging (0.998); catalogued as COSV100611973, COSV59964339; called by muse, mutect2
- TYK2 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 145/586 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs867249402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B15 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 126/492 reads (26%) | catalogued as rs138640811; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs754058667; called by muse, mutect2, varscan2
- UNC5B | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 101/390 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs761496877; called by muse, mutect2, varscan2
- USH2A | c.9077C>T p.P3026L | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56446774; called by muse, mutect2
- USH2A | c.4429G>A p.G1477R | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV56382426, COSV56433659; called by muse, mutect2, varscan2
- USP26 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868304837, COSV63708540; called by muse, mutect2, varscan2
- VPS35L | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 116/469 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs757025573; called by muse, mutect2, varscan2
- VSIG10 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 112/527 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV104420311; called by muse, mutect2, varscan2
- XAB2 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 139/523 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1163947449, COSV50338543; called by muse, mutect2, varscan2
- XXYLT1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 176/676 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs186038785, COSV59987329; called by muse, mutect2, varscan2
- ZDBF2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs866727544, COSV65628505; called by muse, mutect2, varscan2
- ZFHX3 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 129/510 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs867168176; called by muse, mutect2, varscan2
- ZKSCAN3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 219/661 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778775387; called by muse, mutect2, varscan2
- ZNF114 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 119/398 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV100252120; called by muse, mutect2, varscan2
- ZNF208 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 119/489 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68101560, COSV68109475; called by muse, mutect2, varscan2
- ZNF215 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs375915544; called by muse, mutect2, varscan2
- ZNF28 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 112/574 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs574742869; called by muse, varscan2
- ZNF385D | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1305245934, COSV55764730; called by muse, mutect2, varscan2
- ZNF541 | c.2578C>T p.H860Y | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1447474058; called by muse, mutect2, varscan2
- ZNF569 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 114/427 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100386559; called by muse, mutect2, varscan2
- ZNF83 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 117/389 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.201); catalogued as rs1159433383; called by muse, mutect2, varscan2
- ZNF831 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 50/658 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV64039241; called by muse, mutect2
- ZNFX1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757223213, COSV65573995; called by muse, mutect2, varscan2
- ABCB1 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 102/529 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ABCC5 | c.2403T>A p.S801R | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABTB1 | c.787C>T p.P263S (on ENST00000232744 / NM_172027.3; = p.P121S on NM_032548.3) | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACP6 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ACVR1B | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADAMTS20 | c.1686_1687del p.W562* | Nonsense Mutation (DEL) | VAF 106/410 reads (26%) | called by mutect2, pindel*, varscan2
- ADGRE3 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRG4 | c.4960C>T p.P1654S | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALS2CL | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 132/509 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ANK3 | c.10049C>T p.S3350F | Missense Mutation (SNP) | VAF 111/420 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANKRD35 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANO2 | c.2624+1del p.X875_splice (on ENST00000356134 / NM_001278597.3; = p.X879_splice on NM_001278596.3) | Splice Site (DEL) | VAF 62/275 reads (23%) | called by mutect2, pindel, varscan2
- ANXA8 | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- APC2 | c.5036C>T p.S1679F | Missense Mutation (SNP) | VAF 152/648 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARFGEF2 | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMS2 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASL | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 97/507 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ASXL2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 32/443 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.031); called by muse, mutect2
- ATP11A | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 105/633 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2A2 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- ATP2B2 | c.2358T>G p.H786Q (on ENST00000352432; = p.H752Q on NM_001683.5) | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ATP6V1B2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP8A1 | c.3377C>T p.S1126F | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- BMS1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD16 | c.948A>G p.I316M | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- BTBD7 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 131/484 reads (27%) | called by muse, mutect2, varscan2
- C1orf112 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CAMK2D | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 85/313 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CARF | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2
- CASP9 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CCDC168 | c.21146C>T p.P7049L | Missense Mutation (SNP) | VAF 101/649 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC197 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 100/396 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CCL25 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDC45 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDHR4 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 105/406 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDRT15 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CDS2 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.326); called by muse, mutect2
- CFAP157 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 145/374 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CFAP61 | c.2213A>T p.N738I | Missense Mutation (SNP) | VAF 96/403 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CHAF1B | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 183/647 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CHD3 | c.4669A>G p.T1557A | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CHD5 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 159/525 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CKAP2 | c.701C>T p.S234F (on ENST00000378037 / NM_001098525.2; = p.S233F on NM_018204.5) | Missense Mutation (SNP) | VAF 96/726 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CMYA5 | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 100/424 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CNN2 | c.680G>C p.R227P | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CNTNAP2 | c.3496G>A p.E1166K | Missense Mutation (SNP) | VAF 210/494 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- COL5A1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 238/559 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, varscan2
- COMMD8 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CRISP3 | c.277A>G p.K93E (on ENST00000371159 / NM_001368123.1; = p.K75E on NM_006061.4) | Missense Mutation (SNP) | VAF 101/435 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CSPG4 | c.4997C>T p.P1666L | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTAGE15 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by mutect2, varscan2
- DCAF13 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX20 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4B | c.3326C>T p.S1109F | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DGKA | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX16 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 381/1118 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- DLK2 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 224/706 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.6532C>T p.L2178F (on ENST00000445597; = p.L2831F on NM_001367479.1) | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DNAH7 | c.5722C>T p.P1908S | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.7006G>A p.E2336K | Missense Mutation (SNP) | VAF 52/461 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- EBI3 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 89/420 reads (21%) | called by muse, mutect2
- EHF | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 85/317 reads (27%) | called by muse, mutect2, varscan2
- EIF2S3B | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 162/621 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EIF4E3 | c.344G>A p.W115* (on ENST00000425534 / NM_001134651.2; = p.W9* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 52/301 reads (17%) | called by muse, mutect2, varscan2
- ELOVL3 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.241); called by muse, varscan2
- EPPK1 | c.4032G>T p.K1344N | Missense Mutation (SNP) | VAF 293/676 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ERO1B | c.306G>A p.E102= | Splice Region (SNP) | VAF 65/260 reads (25%) | called by muse, mutect2, varscan2
- EXOSC10 | c.2359C>T p.P787S (on ENST00000376936 / NM_001001998.3; = p.P762S on NM_002685.4) | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM13A | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- FAM205A | c.3143G>A p.R1048K | Missense Mutation (SNP) | VAF 64/670 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.281); called by muse, mutect2
- FAT3 | c.2069A>G p.Q690R | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FGF12 | c.628G>A p.E210K (on ENST00000454309 / NM_021032.5; = p.E148K on NM_004113.6) | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FIZ1 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 152/624 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL1 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 104/412 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNIP2 | c.142del p.R48Afs*2 | Frame Shift Del (DEL) | VAF 55/249 reads (22%) | called by mutect2, pindel, varscan2
- FOXD4L3 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.15); called by mutect2, varscan2
- FOXJ2 | c.1725G>T p.*575Yext*14 | Nonstop Mutation (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- FSIP2 | c.5927T>A p.F1976Y | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA5 | c.1084A>C p.I362L | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GCC1 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 258/647 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GJB5 | c.589T>C p.C197R | Missense Mutation (SNP) | VAF 135/473 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT1D1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GPHN | c.799C>T p.P267S (on ENST00000315266 / NM_001377519.1; = p.P300S on NM_020806.5) | Missense Mutation (SNP) | VAF 49/528 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- GPX6 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 159/456 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GREB1L | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GYS1 | c.1637C>A p.S546* | Nonsense Mutation (SNP) | VAF 93/357 reads (26%) | called by muse, mutect2, varscan2
- HELZ2 | c.6374C>T p.P2125L (on ENST00000467148 / NM_001037335.2; = p.P1556L on NM_033405.3) | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- HELZ2 | c.6373C>T p.P2125S (on ENST00000467148 / NM_001037335.2; = p.P1556S on NM_033405.3) | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- HERC2 | c.14397_14399delinsTG p.A4800Dfs*32 | Frame Shift Del (DEL) | VAF 163/897 reads (18%) | called by pindel, varscan2*
- HIVEP3 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 110/498 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- HMGCLL1 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HRH2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 126/462 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HS3ST3B1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HYDIN | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGFN1 | c.3130C>T p.P1044S (on ENST00000295591 / NM_001367841.1; = p.P3501S on NM_001164586.2) | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- IGSF10 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 99/438 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSRR | c.1629G>A p.W543* | Nonsense Mutation (SNP) | VAF 124/465 reads (27%) | called by muse, mutect2, varscan2
- ITPR2 | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN2 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JPT2 | c.103_108del p.T35_P36del | In Frame Del (DEL) | VAF 74/417 reads (18%) | called by mutect2, pindel, varscan2
- KCNE2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 129/559 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNT1 | c.1145A>G p.D382G (on ENST00000488444; = p.D401G on NM_020822.3) | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- KDM4F | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KDM5B | c.3034G>A p.D1012N | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KERA | c.298A>T p.I100L | Missense Mutation (SNP) | VAF 94/449 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- KIAA1522 | c.416C>T p.T139I (on ENST00000373480 / NM_001198972.2; = p.T198I on NM_020888.3) | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF1B | c.5416C>T p.L1806F (on ENST00000377086 / NM_001365952.1; = p.L1760F on NM_015074.3) | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- KIF5C | c.2385_2406del p.Q796Nfs*7 | Frame Shift Del (DEL) | VAF 71/348 reads (20%) | called by mutect2, pindel, varscan2
- KLF12 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 94/625 reads (15%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1318C>T p.P440S (on ENST00000395676; = p.P1081S on NM_138433.5) | Missense Mutation (SNP) | VAF 172/622 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- KLHL6 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 150/596 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 157/553 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KRT76 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 180/738 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, varscan2
- KRT77 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 125/511 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LAPTM5 | c.87+1G>A p.X29_splice | Splice Site (SNP) | VAF 40/403 reads (10%) | called by muse, mutect2, varscan2
- LIFR | c.2022G>A p.W674* | Nonsense Mutation (SNP) | VAF 22/585 reads (4%) | called by muse, mutect2
- LMTK2 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 219/552 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LOXL2 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 149/399 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRP1 | c.5672C>T p.S1891F | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRP1B | c.3863G>A p.R1288K | Missense Mutation (SNP) | VAF 103/396 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LRRC4C | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 91/410 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC63 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 94/688 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LYN | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 119/586 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MAP1A | c.7051C>T p.Q2351* | Nonsense Mutation (SNP) | VAF 154/606 reads (25%) | called by muse, varscan2
- MAP3K10 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 116/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K11 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 165/689 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K19 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAST3 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 105/451 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MCM10 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 134/522 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM2 | c.3783G>A p.M1261I | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- MIB2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 122/542 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRC1 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 100/471 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MROH2B | c.3888G>A p.W1296* | Nonsense Mutation (SNP) | VAF 268/540 reads (50%) | called by muse, mutect2, varscan2
- MSH3 | c.1762A>G p.R588G | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MUC16 | c.17675C>T p.P5892L | Missense Mutation (SNP) | VAF 125/484 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2
- MUC16 | c.14254C>T p.L4752F | Missense Mutation (SNP) | VAF 120/429 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MUC22 | c.2753C>T p.T918I | Missense Mutation (SNP) | VAF 256/990 reads (26%) | SIFT tolerated (0.43); called by muse, mutect2, varscan2
- MYH8 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO7A | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NAALAD2 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NACC2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 128/682 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL1 | c.6838C>T p.P2280S | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBPF12 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 31/317 reads (10%) | called by muse, mutect2, varscan2
- NCBP1 | c.2224A>G p.N742D | Missense Mutation (SNP) | VAF 93/453 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NCOA6 | c.5492C>T p.A1831V | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NECTIN3 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 93/373 reads (25%) | called by muse, mutect2, varscan2
- NELL1 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN2 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2
- NLRP11 | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NOL9 | c.1142A>C p.N381T | Missense Mutation (SNP) | VAF 107/423 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NOM1 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 177/471 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NOP2 | c.2074C>T p.P692S (on ENST00000322166 / NM_001258308.2; = p.P688S on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/545 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- NUFIP2 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 95/419 reads (23%) | called by muse, mutect2, varscan2
- NYAP1 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 149/819 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OBSCN | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ODF3 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGDH | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 69/369 reads (19%) | called by muse, mutect2, varscan2
- OR10Q1 | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 124/503 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR1N2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 100/561 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR2W1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 213/561 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR4D2 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 154/578 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR6C1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OVGP1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 140/546 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PALM3 | c.1165G>A p.E389K (on ENST00000340790; = p.E404K on NM_001145028.2) | Missense Mutation (SNP) | VAF 143/600 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDHA10 | c.1388T>A p.V463E | Missense Mutation (SNP) | VAF 188/374 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCNX2 | c.5230G>A p.E1744K | Missense Mutation (SNP) | VAF 113/473 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PDE2A | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PEDS1 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX10 | c.546T>G p.F182L | Missense Mutation (SNP) | VAF 132/491 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF7 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 113/454 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIK3CA | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- PKHD1L1 | c.9739A>T p.S3247C | Missense Mutation (SNP) | VAF 175/423 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PLA2G4F | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLEC | c.564G>A p.W188* (on ENST00000322810 / NM_201380.4; = p.W78* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 112/572 reads (20%) | called by muse, mutect2, varscan2
- PLXDC1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 144/563 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- POLR1B | c.3070C>T p.Q1024* | Nonsense Mutation (SNP) | VAF 95/361 reads (26%) | called by muse, mutect2, varscan2
- POLR2A | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR3B | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- POTEB3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by mutect2, varscan2
- POTEG | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 59/1182 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.323); called by muse, mutect2
- PROKR2 | c.857T>A p.L286Q | Missense Mutation (SNP) | VAF 119/468 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PRSS16 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 174/594 reads (29%) | called by muse, mutect2, varscan2
- PSMC2 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTOV1 | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 115/450 reads (26%) | called by muse, mutect2, varscan2
- PTPN18 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRT | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 61/241 reads (25%) | called by muse, mutect2, varscan2
- PYROXD2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 130/474 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.025); called by muse, varscan2
- QKI | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 121/286 reads (42%) | called by muse, mutect2, varscan2
- RDM1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- REG3G | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 128/504 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- RGSL1 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RHCG | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 163/571 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RILPL2 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 145/467 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RIMKLA | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- RNF216 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 84/478 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ROBO2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL37A | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated, low confidence (0.46); called by muse, mutect2, varscan2
- RXRB | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCRN3 | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SHANK2 | c.3314C>G p.T1105R | Missense Mutation (SNP) | VAF 130/525 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SHANK3 | c.1733T>G p.V578G | Missense Mutation (SNP) | VAF 101/401 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHD | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 149/540 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- SKIV2L | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 304/887 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLC12A8 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 128/562 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A7 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A11 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 130/493 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SLC6A11 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A8 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 59/245 reads (24%) | called by muse, varscan2
- SMARCC2 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SNX7 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- SON | c.5278G>A p.D1760N | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPDYE1 | c.547-2_550del p.X183_splice | Splice Site (DEL) | VAF 97/332 reads (29%) | called by mutect2, pindel, varscan2
- SPEF2 | c.4224A>T p.E1408D | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SPOCD1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRFBP1 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRSF2 | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 120/491 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT6 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STEAP4 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2
- STYK1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SVEP1 | c.5323C>T p.P1775S | Missense Mutation (SNP) | VAF 121/333 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SVEP1 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 84/487 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D9B | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 57/277 reads (21%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2418C>T p.V806= | Splice Region (SNP) | VAF 56/276 reads (20%) | called by muse, mutect2, varscan2
- TBL3 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 116/497 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- TEP1 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TMEM117 | c.695T>C p.L232S | Missense Mutation (SNP) | VAF 151/533 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM211 | c.403G>A p.E135K (on ENST00000423535; = p.E64K on NM_001001663.3) | Missense Mutation (SNP) | VAF 124/471 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TMEM211 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 56/234 reads (24%) | called by muse, mutect2, varscan2
- TMEM63B | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 196/608 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM65 | c.472+1G>C p.X158_splice | Splice Site (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- TMEM92 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 150/683 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2
- TNFRSF8 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TNR | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 145/513 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNS4 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 160/604 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TOX2 | c.1232C>T p.P411L (on ENST00000358131 / NM_001098798.2; = p.P387L on NM_032883.3) | Missense Mutation (SNP) | VAF 133/492 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRIM45 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 130/479 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TRIP10 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TRPM4 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 134/539 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPV5 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 48/832 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.968); called by muse, mutect2
- TSPAN13 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 158/428 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC38 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 39/536 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- TTC6 | c.1426G>A p.A476T (on ENST00000267368; = p.A1842T on NM_001310135.3) | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TTN | c.101023G>A p.E33675K (on ENST00000591111; = p.E26251K on NM_003319.4) | Missense Mutation (SNP) | VAF 109/491 reads (22%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.54950G>A p.G18317E (on ENST00000591111; = p.G10893E on NM_003319.4) | Missense Mutation (SNP) | VAF 104/447 reads (23%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TYK2 | c.1712C>G p.P571R | Missense Mutation (SNP) | VAF 144/585 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- UBLCP1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UGT3A1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 205/453 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- USP31 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 113/375 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP9X | c.4068_4072del p.L1357Yfs*12 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | called by pindel, varscan2
- VPS18 | c.1564T>G p.C522G | Missense Mutation (SNP) | VAF 130/482 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS39 | c.1036C>T p.H346Y (on ENST00000348544 / NM_001301138.2; = p.H335Y on NM_015289.5) | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VWDE | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WDR53 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 112/415 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- XAF1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 83/387 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.8404C>T p.Q2802* (on ENST00000628543; = p.Q2977* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 96/390 reads (25%) | called by muse, mutect2, varscan2
- XK | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZAN | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 245/600 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZC3HAV1 | c.444G>A p.E148= | Splice Region (SNP) | VAF 91/374 reads (24%) | called by muse, mutect2, varscan2
- ZNF169 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 212/562 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZNF224 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 105/443 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF630 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 162/341 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF665 | c.1166G>A p.G389E (on ENST00000600412; = p.G454E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/549 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF737 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 58/211 reads (27%) | called by muse, mutect2, varscan2
- ZNF777 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF8 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ZRANB3 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCG8 | c.1224C>T p.S408= | Silent (SNP) | VAF 69/247 reads (28%) | catalogued as rs1189257164, COSV55396556; called by muse, mutect2, varscan2
- ACSM1 | c.48C>T p.S16= | Silent (SNP) | VAF 90/408 reads (22%) | catalogued as COSV54636849; called by muse, varscan2
- ACTL7A | c.1149C>T p.P383= | Silent (SNP) | VAF 253/612 reads (41%) | called by muse, mutect2, varscan2
- ADAM15 | c.798C>T p.T266= | Silent (SNP) | VAF 94/447 reads (21%) | called by muse, mutect2, varscan2
- ADAM33 | c.1689C>T p.F563= | Silent (SNP) | VAF 23/393 reads (6%) | catalogued as rs1047691117; called by muse, mutect2
- ADAMTS10 | c.447C>T p.I149= | Silent (SNP) | VAF 84/322 reads (26%) | catalogued as rs782556409, COSV54353780; called by muse, mutect2, varscan2
- ADAR | c.3093C>T p.L1031= | Silent (SNP) | VAF 34/500 reads (7%) | called by muse, mutect2
- ADCY7 | c.2143C>T p.L715= | Silent (SNP) | VAF 83/382 reads (22%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2448C>T p.A816= | Silent (SNP) | VAF 74/284 reads (26%) | called by muse, mutect2
- ADGRL3 | c.501G>A p.V167= (on ENST00000506720 / NM_001322402.2; = p.V99= on NM_015236.6) | Silent (SNP) | VAF 123/405 reads (30%) | catalogued as rs774500508; called by muse, mutect2, varscan2
- ADRA2A | c.255C>T p.L85= | Silent (SNP) | VAF 158/557 reads (28%) | called by muse, mutect2, varscan2
- AGTR1 | c.858C>T p.I286= | Silent (SNP) | VAF 89/366 reads (24%) | called by muse, mutect2, varscan2
- AHR | c.1365C>T p.S455= | Silent (SNP) | VAF 39/578 reads (7%) | called by muse, mutect2
- AKR1A1 | c.930C>T p.V310= | Silent (SNP) | VAF 72/310 reads (23%) | catalogued as rs774056064; called by muse, mutect2, varscan2
- AKR1D1 | c.324C>T p.V108= | Silent (SNP) | VAF 70/372 reads (19%) | catalogued as rs762814083, COSV54336041; called by muse, mutect2, varscan2
- ANKS3 | c.327C>T p.A109= | Silent (SNP) | VAF 148/470 reads (31%) | catalogued as COSV58507563; called by muse, mutect2, varscan2
- AOC3 | c.1128C>T p.S376= | Silent (SNP) | VAF 152/497 reads (31%) | called by muse, mutect2, varscan2
- AP002495.1 | c.360C>T p.L120= (on ENST00000528511; = p.L51= on NM_001375848.1) | Silent (SNP) | VAF 120/468 reads (26%) | catalogued as rs1236173894; called by muse, mutect2, varscan2
- ARHGAP29 | c.2460C>T p.F820= | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as COSV53109495; called by muse, mutect2, varscan2
- ART4 | c.285G>A p.R95= | Silent (SNP) | VAF 34/526 reads (6%) | called by muse, mutect2
- ASB10 | c.564C>T p.C188= (on ENST00000420175 / NM_001142459.2; = p.C173= on NM_080871.4) | Silent (SNP) | VAF 201/494 reads (41%) | catalogued as CM121518; called by muse, mutect2, varscan2
- ASB5 | c.558C>T p.I186= | Silent (SNP) | VAF 104/386 reads (27%) | catalogued as COSV56672268; called by muse, mutect2, varscan2
- ATP11A | c.498C>T p.F166= | Silent (SNP) | VAF 104/634 reads (16%) | catalogued as COSV52126823; called by muse, mutect2, varscan2
- ATP2B2 | c.2811C>T p.S937= (on ENST00000352432; = p.S903= on NM_001683.5) | Silent (SNP) | VAF 84/418 reads (20%) | called by muse, mutect2, varscan2
- ATP8A1 | c.2616C>T p.I872= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as rs755858752, COSV52540383; called by muse, mutect2, varscan2
- ATXN7L2 | c.180C>T p.T60= | Silent (SNP) | VAF 74/331 reads (22%) | catalogued as rs760914122; called by muse, mutect2, varscan2
- B4GALNT3 | c.1102C>A p.R368= | Silent (SNP) | VAF 75/322 reads (23%) | catalogued as COSV99842665; called by muse, mutect2, varscan2
- B4GALNT4 | c.249G>A p.E83= | Silent (SNP) | VAF 70/353 reads (20%) | called by muse, mutect2
- BAHCC1 | c.5499G>A p.K1833= | Silent (SNP) | VAF 96/427 reads (22%) | called by muse, mutect2, varscan2
- BTK | c.183C>T p.I61= | Silent (SNP) | VAF 98/204 reads (48%) | called by muse, mutect2, varscan2
- C14orf180 | c.282C>T p.P94= | Silent (SNP) | VAF 138/574 reads (24%) | catalogued as rs892171831; called by muse, mutect2, varscan2
- C16orf71 | c.612G>A p.R204= | Silent (SNP) | VAF 136/479 reads (28%) | catalogued as COSV54794601; called by muse, mutect2, varscan2
- C1orf105 | c.456C>T p.F152= | Silent (SNP) | VAF 82/398 reads (21%) | catalogued as COSV100877984; called by muse, mutect2, varscan2
- CACNA1E | c.4566C>T p.S1522= | Silent (SNP) | VAF 41/528 reads (8%) | catalogued as COSV62403513; called by muse, mutect2
- CALM3 | c.159C>T p.I53= | Silent (SNP) | VAF 101/410 reads (25%) | catalogued as rs375106354; called by muse, mutect2, varscan2
- CAPN13 | c.672C>T p.S224= | Silent (SNP) | VAF 83/368 reads (23%) | called by muse, mutect2, varscan2
- CARMIL2 | c.405C>T p.S135= | Silent (SNP) | VAF 100/442 reads (23%) | catalogued as COSV100575908; called by muse, mutect2, varscan2
- CARS1 | c.2097C>T p.S699= | Silent (SNP) | VAF 110/433 reads (25%) | called by muse, mutect2, varscan2
- CASR | c.711C>T p.I237= | Silent (SNP) | VAF 125/423 reads (30%) | catalogued as rs778379455, COSV56141421; called by muse, mutect2, varscan2
- CCDC173 | c.1611A>G p.P537= | Silent (SNP) | VAF 81/320 reads (25%) | called by muse, mutect2, varscan2
- CCDC27 | c.774C>T p.L258= | Silent (SNP) | VAF 96/377 reads (25%) | catalogued as COSV53898474; called by muse, mutect2, varscan2
- CCDC87 | c.1248C>T p.P416= | Silent (SNP) | VAF 112/510 reads (22%) | called by muse, mutect2, varscan2
- CD300E | c.129G>A p.K43= | Silent (SNP) | VAF 92/412 reads (22%) | called by muse, mutect2, varscan2
- CDH6 | c.1329G>A p.S443= | Silent (SNP) | VAF 237/523 reads (45%) | catalogued as rs142200699; called by muse, mutect2, varscan2
- CDRT1 | c.834C>T p.I278= | Silent (SNP) | VAF 100/345 reads (29%) | called by muse, mutect2, varscan2
- CELSR3 | c.9681G>A p.R3227= | Silent (SNP) | VAF 138/515 reads (27%) | called by muse, mutect2, varscan2
- CFAP58 | c.1422G>A p.R474= | Silent (SNP) | VAF 84/332 reads (25%) | catalogued as rs376065077; called by muse, varscan2
- CKAP2 | c.702C>T p.S234= (on ENST00000378037 / NM_001098525.2; = p.S233= on NM_018204.5) | Silent (SNP) | VAF 96/724 reads (13%) | called by muse, mutect2, varscan2
- CKAP2 | c.1227C>T p.T409= (on ENST00000378037 / NM_001098525.2; = p.T408= on NM_018204.5) | Silent (SNP) | VAF 100/616 reads (16%) | called by muse, mutect2, varscan2
- CLEC19A | c.75C>T p.I25= | Silent (SNP) | VAF 89/377 reads (24%) | called by muse, mutect2, varscan2
- COQ10B | c.373T>C p.L125= | Silent (SNP) | VAF 72/302 reads (24%) | called by muse, mutect2, varscan2
- CPNE1 | c.576C>T p.F192= (on ENST00000352393; = p.F197= on NM_003915.5) | Silent (SNP) | VAF 88/376 reads (23%) | catalogued as COSV100467743; called by muse, mutect2, varscan2
- CPNE9 | c.1374C>T p.I458= | Silent (SNP) | VAF 114/434 reads (26%) | catalogued as rs762670962, COSV56067592; called by muse, mutect2, varscan2
- CRAMP1 | c.246C>T p.F82= | Silent (SNP) | VAF 122/465 reads (26%) | catalogued as rs769727202; called by muse, mutect2, varscan2
- CRYGC | c.504G>A p.R168= | Silent (SNP) | VAF 97/328 reads (30%) | catalogued as COSV52204838; called by muse, mutect2, varscan2
- CSPG4 | c.4998C>T p.P1666= | Silent (SNP) | VAF 112/407 reads (28%) | called by muse, mutect2, varscan2
- CTH | c.945C>T p.T315= | Silent (SNP) | VAF 82/360 reads (23%) | called by muse, mutect2, varscan2
- CUX1 | c.1722C>T p.F574= | Silent (SNP) | VAF 235/597 reads (39%) | catalogued as rs1554518620; called by muse, mutect2, varscan2
- CYP2C19 | c.678C>T p.F226= | Silent (SNP) | VAF 58/238 reads (24%) | catalogued as rs1316237390, COSV64906794; called by muse, mutect2, varscan2
- DAGLB | c.180C>T p.I60= | Silent (SNP) | VAF 228/573 reads (40%) | catalogued as rs1284719136; called by muse, mutect2, varscan2
- DDX49 | c.312C>T p.I104= | Silent (SNP) | VAF 98/393 reads (25%) | catalogued as rs1334029750; called by muse, mutect2, varscan2
- DENND3 | c.450G>A p.A150= | Silent (SNP) | VAF 105/502 reads (21%) | catalogued as rs267601799, COSV99371076; called by muse, mutect2, varscan2
- DIO3 | c.909G>A p.R303= | Silent (SNP) | VAF 66/257 reads (26%) | called by muse, mutect2, varscan2
- DNAH10 | c.8271G>A p.L2757= (on ENST00000409039; = p.L2696= on NM_207437.3) | Silent (SNP) | VAF 125/500 reads (25%) | called by muse, mutect2, varscan2
- DSG3 | c.276C>T p.I92= | Silent (SNP) | VAF 112/425 reads (26%) | catalogued as rs768144069, COSV57126509, COSV99934744; called by muse, mutect2, varscan2
- DYRK1B | c.546C>T p.F182= | Silent (SNP) | VAF 63/314 reads (20%) | catalogued as rs1403212008, COSV59914166; called by muse, mutect2, varscan2
- EIF4G1 | c.4725G>A p.K1575= (on ENST00000346169 / NM_198241.3; = p.K1380= on NM_004953.5) | Silent (SNP) | VAF 110/452 reads (24%) | called by muse, mutect2, varscan2
- ENO1 | c.1008C>T p.S336= | Silent (SNP) | VAF 109/430 reads (25%) | called by muse, mutect2, varscan2
- EP400 | c.126C>T p.F42= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as rs139666996, COSV57764426; called by muse, mutect2, varscan2
- EPHA8 | c.2748C>T p.F916= | Silent (SNP) | VAF 136/497 reads (27%) | catalogued as rs150592901; called by muse, mutect2, varscan2
- FAM135B | c.879G>A p.L293= | Silent (SNP) | VAF 76/316 reads (24%) | called by muse, mutect2, varscan2
- FAM13A | c.1086C>T p.T362= | Silent (SNP) | VAF 90/361 reads (25%) | catalogued as rs138392660; called by muse, mutect2, varscan2
- FAM209B | c.267C>T p.G89= | Silent (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- FAM47A | c.2352C>T p.I784= | Silent (SNP) | VAF 75/138 reads (54%) | catalogued as rs267606440, COSV60494156; called by muse, mutect2, varscan2
- FAT2 | c.9216C>T p.A3072= | Silent (SNP) | VAF 21/327 reads (6%) | catalogued as rs767338162; called by muse, mutect2
- FGF6 | c.459C>T p.F153= | Silent (SNP) | VAF 55/296 reads (19%) | catalogued as rs149687656; called by muse, mutect2, varscan2
- FKBP1C | c.117C>T p.S39= | Silent (SNP) | VAF 259/752 reads (34%) | called by muse, mutect2, varscan2
- FKBP4 | c.696G>A p.K232= | Silent (SNP) | VAF 92/381 reads (24%) | called by muse, mutect2, varscan2
- FLNB | c.6355C>T p.L2119= | Silent (SNP) | VAF 74/314 reads (24%) | called by muse, mutect2, varscan2
- FOXN3 | c.1290C>T p.V430= (on ENST00000261302; = p.V408= on NM_005197.4) | Silent (SNP) | VAF 103/494 reads (21%) | called by muse, mutect2, varscan2
- FTMT | c.84C>T p.L28= | Silent (SNP) | VAF 146/522 reads (28%) | catalogued as COSV100360412, COSV58419873; called by muse, mutect2, varscan2
- GALNT13 | c.117G>A p.E39= | Silent (SNP) | VAF 95/401 reads (24%) | called by muse, mutect2, varscan2
- GCC2 | c.3423C>T p.T1141= | Silent (SNP) | VAF 46/260 reads (18%) | called by muse, mutect2, varscan2
- GIMAP1 | c.909C>T p.V303= | Silent (SNP) | VAF 178/454 reads (39%) | catalogued as rs573193854, COSV56189546; called by muse, mutect2, varscan2
- GLIPR1L2 | c.258G>A p.R86= | Silent (SNP) | VAF 53/265 reads (20%) | catalogued as COSV57555423; called by muse, mutect2, varscan2
- GMPR | c.639G>A p.K213= | Silent (SNP) | VAF 183/609 reads (30%) | catalogued as rs199679326; called by muse, mutect2, varscan2
- GPR173 | c.181C>T p.L61= | Silent (SNP) | VAF 161/338 reads (48%) | called by muse, mutect2, varscan2
- GRIK1 | c.681G>A p.V227= | Silent (SNP) | VAF 79/348 reads (23%) | called by muse, mutect2, varscan2
- H2AC21 | c.312C>T p.A104= | Silent (SNP) | VAF 104/410 reads (25%) | catalogued as rs1553760077; called by muse, mutect2, varscan2
- H2BC12 | c.315G>A p.G105= | Silent (SNP) | VAF 248/821 reads (30%) | catalogued as rs377124176; called by muse, mutect2, varscan2
- HCN2 | c.1866G>C p.V622= | Silent (SNP) | VAF 40/420 reads (10%) | called by muse, mutect2
- HERC1 | c.11676G>A p.V3892= | Silent (SNP) | VAF 118/428 reads (28%) | called by muse, mutect2, varscan2
- HSPG2 | c.10843C>T p.L3615= | Silent (SNP) | VAF 90/362 reads (25%) | catalogued as rs1392934049; called by muse, mutect2, varscan2
- HTR5A | c.354C>T p.I118= | Silent (SNP) | VAF 117/613 reads (19%) | catalogued as COSV55280956; called by muse, mutect2, varscan2
- IBA57 | c.298C>T p.L100= | Silent (SNP) | VAF 129/513 reads (25%) | catalogued as COSV64510749; called by muse, mutect2, varscan2
- ID4 | c.339C>T p.A113= | Silent (SNP) | VAF 199/769 reads (26%) | called by muse, mutect2, varscan2
- IGKV1-17 | c.240C>T p.V80= | Silent (SNP) | VAF 119/545 reads (22%) | called by muse, mutect2, varscan2
- IGSF9B | c.3714C>T p.T1238= | Silent (SNP) | VAF 146/610 reads (24%) | called by muse, mutect2, varscan2
- ILF2 | c.102C>T p.F34= | Silent (SNP) | VAF 88/369 reads (24%) | catalogued as rs769871746; called by muse, mutect2, varscan2
- INSRR | c.3270G>A p.G1090= | Silent (SNP) | VAF 87/337 reads (26%) | called by muse, mutect2, varscan2
- INTS4 | c.948C>T p.F316= | Silent (SNP) | VAF 87/332 reads (26%) | catalogued as COSV101417097; called by muse, mutect2, varscan2
- ITPR1 | c.558C>T p.P186= | Silent (SNP) | VAF 73/316 reads (23%) | catalogued as rs377387496; called by muse, mutect2, varscan2
- JMJD4 | c.1122C>T p.S374= | Silent (SNP) | VAF 66/312 reads (21%) | catalogued as rs186121628; called by muse, mutect2, varscan2
- KAT6A | c.3537C>T p.I1179= | Silent (SNP) | VAF 171/438 reads (39%) | called by muse, mutect2, varscan2
- KCNA7 | c.1209G>A p.R403= | Silent (SNP) | VAF 148/584 reads (25%) | called by muse, mutect2
- KCNC2 | c.1473G>A p.R491= | Silent (SNP) | VAF 113/412 reads (27%) | catalogued as rs1262731100, COSV100129271; called by muse, mutect2, varscan2
- KCNK10 | c.336C>T p.F112= | Silent (SNP) | VAF 154/506 reads (30%) | catalogued as COSV56652545; called by muse, varscan2
- KCNQ2 | c.1587C>T p.T529= (on ENST00000359125 / NM_172107.4; = p.T501= on NM_004518.6) | Silent (SNP) | VAF 156/502 reads (31%) | catalogued as rs753417293; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA0100 | c.1146C>T p.H382= | Silent (SNP) | VAF 116/442 reads (26%) | catalogued as rs958981006; called by muse, mutect2, varscan2
- KIAA0513 | c.669G>A p.K223= | Silent (SNP) | VAF 119/544 reads (22%) | catalogued as COSV99260644; called by muse, mutect2, varscan2
- KIAA1210 | c.2412C>T p.S804= | Silent (SNP) | VAF 118/269 reads (44%) | called by muse, mutect2, varscan2
- KIAA1614 | c.3045G>A p.Q1015= | Silent (SNP) | VAF 150/547 reads (27%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4575G>A p.K1525= | Silent (SNP) | VAF 111/447 reads (25%) | called by muse, mutect2, varscan2
- KIFC3 | c.1038C>T p.A346= | Silent (SNP) | VAF 116/495 reads (23%) | catalogued as COSV101109157; called by muse, mutect2, varscan2
- KLRF2 | c.415C>T p.L139= | Silent (SNP) | VAF 71/315 reads (23%) | called by muse, mutect2, varscan2
- KRT1 | c.600C>T p.F200= | Silent (SNP) | VAF 68/276 reads (25%) | catalogued as COSV99359047; called by muse, mutect2, varscan2
- KRT6A | c.111C>T p.S37= | Silent (SNP) | VAF 187/694 reads (27%) | catalogued as rs754048248, COSV58104872; called by muse, mutect2, varscan2
- KRTAP2-1 | c.246G>C p.S82= | Silent (SNP) | VAF 42/812 reads (5%) | catalogued as rs1163311263; called by muse, mutect2
- KRTAP2-3 | c.246G>C p.S82= | Silent (SNP) | VAF 88/812 reads (11%) | called by muse, mutect2, varscan2
- LANCL1 | c.253C>T p.L85= | Silent (SNP) | VAF 112/430 reads (26%) | called by muse, mutect2, varscan2
- LGALS12 | c.825G>A p.G275= | Silent (SNP) | VAF 126/463 reads (27%) | catalogued as rs1293361583; called by muse, mutect2, varscan2
- LGMN | c.339C>T p.F113= | Silent (SNP) | VAF 63/247 reads (26%) | catalogued as COSV58402729; called by muse, mutect2, varscan2
- LRP1B | c.2212T>C p.L738= | Silent (SNP) | VAF 91/353 reads (26%) | catalogued as COSV67285902; called by muse, mutect2, varscan2
- MAGI1 | c.2706C>A p.P902= (on ENST00000402939 / NM_001033057.2; = p.P930= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/257 reads (23%) | called by muse, mutect2, varscan2
- MARCHF4 | c.540C>T p.R180= | Silent (SNP) | VAF 69/409 reads (17%) | called by muse, mutect2, varscan2
- MC5R | c.576C>T p.S192= | Silent (SNP) | VAF 102/439 reads (23%) | catalogued as COSV61254659; called by muse, mutect2, varscan2
- MCM7 | c.1816C>T p.L606= | Silent (SNP) | VAF 96/557 reads (17%) | catalogued as rs1308273469; called by muse, mutect2, varscan2
- MMEL1 | c.2061C>T p.A687= | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as rs1411177003; called by muse, mutect2, varscan2
- MPIG6B | c.432G>A p.L144= | Silent (SNP) | VAF 308/864 reads (36%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 111/500 reads (22%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MRRF | c.264G>A p.V88= | Silent (SNP) | VAF 83/537 reads (15%) | called by muse, mutect2, varscan2
- MTA3 | c.1338C>T p.A446= | Silent (SNP) | VAF 76/380 reads (20%) | catalogued as COSV63196981; called by muse, mutect2
- MUC16 | c.15957G>A p.G5319= | Silent (SNP) | VAF 81/473 reads (17%) | called by muse, mutect2, varscan2
- MUC4 | c.13194C>T p.F4398= (on ENST00000463781 / NM_018406.7; = p.F162= on NM_004532.6) | Silent (SNP) | VAF 171/648 reads (26%) | catalogued as rs756736459; called by muse, mutect2, varscan2
- MYO15A | c.7578G>A p.L2526= | Silent (SNP) | VAF 140/580 reads (24%) | called by muse, mutect2, varscan2
- MYO16 | c.2628C>T p.S876= | Silent (SNP) | VAF 312/649 reads (48%) | catalogued as rs779757535; called by muse, mutect2, varscan2
- MYO18B | c.909G>A p.G303= | Silent (SNP) | VAF 140/580 reads (24%) | called by muse, mutect2, varscan2
- NBPF11 | c.1374C>T p.S458= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as rs1163685965; called by muse, mutect2, varscan2
- NCF1 | c.994C>T p.L332= | Silent (SNP) | VAF 95/618 reads (15%) | catalogued as rs1554414927; called by muse, mutect2, varscan2
- NCKAP5 | c.2874C>T p.T958= | Silent (SNP) | VAF 134/517 reads (26%) | called by muse, mutect2, varscan2
- NEB | c.12228C>A p.V4076= | Silent (SNP) | VAF 123/505 reads (24%) | called by muse, mutect2, varscan2
- NELFB | c.657G>A p.E219= | Silent (SNP) | VAF 217/554 reads (39%) | called by muse, mutect2, varscan2
- NEURL1B | c.1257C>T p.F419= | Silent (SNP) | VAF 59/278 reads (21%) | called by muse, mutect2, varscan2
- NKG7 | c.177G>A p.Q59= | Silent (SNP) | VAF 118/456 reads (26%) | catalogued as rs753787107; called by muse, mutect2, varscan2
- NLRC5 | c.3876G>A p.L1292= | Silent (SNP) | VAF 128/434 reads (29%) | called by muse, mutect2, varscan2
- NLRP8 | c.1680C>T p.F560= | Silent (SNP) | VAF 82/354 reads (23%) | catalogued as rs1382822080, COSV52585343; called by muse, mutect2, varscan2
- NLRP9 | c.237C>T p.I79= | Silent (SNP) | VAF 69/370 reads (19%) | called by muse, mutect2, varscan2
- NOA1 | c.1689C>T p.I563= | Silent (SNP) | VAF 89/338 reads (26%) | called by muse, mutect2, varscan2
- NOBOX | c.1623C>T p.F541= | Silent (SNP) | VAF 30/604 reads (5%) | catalogued as COSV56193121; called by muse, mutect2
- NOC2L | c.1071C>T p.F357= | Silent (SNP) | VAF 118/452 reads (26%) | called by muse, mutect2, varscan2
- NOS3 | c.1281C>T p.F427= | Silent (SNP) | VAF 130/626 reads (21%) | catalogued as rs543920266; called by muse, mutect2, varscan2
- NRXN1 | c.975G>A p.G325= | Silent (SNP) | VAF 117/451 reads (26%) | called by muse, mutect2, varscan2
- NUFIP2 | c.243C>T p.L81= | Silent (SNP) | VAF 96/424 reads (23%) | called by muse, mutect2, varscan2
- NUP155 | c.789C>T p.F263= (on ENST00000231498 / NM_153485.3; = p.F204= on NM_004298.4) | Silent (SNP) | VAF 81/546 reads (15%) | catalogued as COSV51527075; called by muse, mutect2, varscan2
- OBSCN | c.13242C>T p.F4414= | Silent (SNP) | VAF 99/387 reads (26%) | called by muse, mutect2, varscan2
- OR10H2 | c.339C>T p.F113= | Silent (SNP) | VAF 153/661 reads (23%) | called by muse, varscan2
- OR10H3 | c.63C>T p.P21= | Silent (SNP) | VAF 88/402 reads (22%) | called by muse, mutect2, varscan2
- OR4C6 | c.393G>A p.T131= | Silent (SNP) | VAF 102/462 reads (22%) | catalogued as rs1218031042, COSV58602697, COSV58605476; called by muse, mutect2, varscan2
- OR51B5 | c.267G>A p.E89= | Silent (SNP) | VAF 99/445 reads (22%) | called by muse, mutect2, varscan2
- OR5I1 | c.603C>T p.L201= | Silent (SNP) | VAF 112/453 reads (25%) | catalogued as COSV56886427; called by muse, mutect2, varscan2
- OR5J2 | c.93C>T p.F31= | Silent (SNP) | VAF 93/365 reads (25%) | catalogued as rs531423583; called by muse, mutect2, varscan2
- PAK5 | c.1443C>T p.D481= | Silent (SNP) | VAF 121/433 reads (28%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1389G>A p.V463= | Silent (SNP) | VAF 112/436 reads (26%) | called by muse, mutect2, varscan2
- PAX9 | c.189G>C p.T63= | Silent (SNP) | VAF 53/625 reads (8%) | catalogued as rs756776471; called by muse, mutect2
- PBXIP1 | c.1852C>T p.L618= | Silent (SNP) | VAF 87/367 reads (24%) | called by muse, mutect2, varscan2
- PCDHB12 | c.310C>T p.L104= | Silent (SNP) | VAF 100/383 reads (26%) | catalogued as rs1554286618; called by muse, mutect2, varscan2
- PCDHB7 | c.744G>A p.K248= | Silent (SNP) | VAF 131/463 reads (28%) | catalogued as rs1400477202; called by muse, mutect2, varscan2
- PCF11 | c.3555T>A p.A1185= | Silent (SNP) | VAF 88/336 reads (26%) | called by muse, mutect2, varscan2
- PCK2 | c.1536G>A p.L512= | Silent (SNP) | VAF 119/520 reads (23%) | catalogued as rs755925235; called by muse, mutect2
- PCLO | c.4023G>A p.K1341= | Silent (SNP) | VAF 68/345 reads (20%) | catalogued as COSV61621488, COSV61634106; called by muse, mutect2, varscan2
- PHC1 | c.783C>T p.S261= | Silent (SNP) | VAF 47/303 reads (16%) | called by muse, mutect2, varscan2
- PIEZO2 | c.5907C>T p.I1969= | Silent (SNP) | VAF 82/319 reads (26%) | catalogued as rs558783355; called by muse, varscan2
- PKHD1L1 | c.6561G>A p.G2187= | Silent (SNP) | VAF 32/661 reads (5%) | catalogued as rs1054460478; called by muse, mutect2
- PLB1 | c.2694C>T p.N898= | Silent (SNP) | VAF 78/346 reads (23%) | catalogued as rs1374280909; called by muse, mutect2, varscan2
- PLEKHB1 | c.426C>T p.R142= | Silent (SNP) | VAF 133/478 reads (28%) | called by muse, mutect2, varscan2
- POLE | c.6150C>T p.F2050= | Silent (SNP) | VAF 60/258 reads (23%) | catalogued as rs1555220911; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR3A | c.219G>A p.G73= | Silent (SNP) | VAF 111/419 reads (26%) | called by muse, mutect2, varscan2
- POM121L12 | c.687C>T p.F229= | Silent (SNP) | VAF 246/685 reads (36%) | catalogued as rs377744248, COSV68692454; called by muse, mutect2, varscan2
- POTEI | c.2193C>T p.F731= | Silent (SNP) | VAF 23/346 reads (7%) | catalogued as rs780611263; called by muse, mutect2, varscan2
- PRAMEF20 | c.207G>C p.L69= | Silent (SNP) | VAF 52/586 reads (9%) | called by muse, mutect2
- PRPS1 | c.759C>T p.F253= | Silent (SNP) | VAF 129/286 reads (45%) | catalogued as rs757148256; called by muse, mutect2, varscan2
- PRPS2 | c.276C>T p.F92= | Silent (SNP) | VAF 124/249 reads (50%) | catalogued as rs1346657940, COSV66126657; called by muse, mutect2, varscan2
- PRSS16 | c.1206C>T p.S402= | Silent (SNP) | VAF 172/595 reads (29%) | catalogued as COSV57915226; called by muse, mutect2, varscan2
- PTPRQ | c.5004G>A p.G1668= (on ENST00000616559; = p.G1626= on NM_001145026.2) | Silent (SNP) | VAF 57/282 reads (20%) | catalogued as rs1382996632; called by muse, mutect2, varscan2
- RADIL | c.627C>T p.P209= | Silent (SNP) | VAF 296/779 reads (38%) | catalogued as COSV101271640; called by muse, mutect2, varscan2
- RASSF9 | c.519G>A p.Q173= | Silent (SNP) | VAF 96/407 reads (24%) | called by muse, mutect2, varscan2
- RBP3 | c.1656C>T p.F552= | Silent (SNP) | VAF 142/536 reads (26%) | catalogued as rs1252102322; called by muse, mutect2, varscan2
- RET | c.1098G>A p.E366= | Silent (SNP) | VAF 96/387 reads (25%) | called by muse, mutect2, varscan2
- RNF216 | c.111C>T p.S37= | Silent (SNP) | VAF 85/478 reads (18%) | called by muse, mutect2, varscan2
- ROR2 | c.1659C>T p.F553= | Silent (SNP) | VAF 235/609 reads (39%) | catalogued as COSV65223385; called by muse, mutect2, varscan2
- RPGRIP1 | c.2331C>T p.T777= | Silent (SNP) | VAF 94/419 reads (22%) | catalogued as rs760801598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6KA4 | c.1059C>T p.P353= | Silent (SNP) | VAF 97/377 reads (26%) | catalogued as rs763050103; called by muse, mutect2, varscan2
- RYR3 | c.4467G>A p.R1489= | Silent (SNP) | VAF 128/488 reads (26%) | called by muse, mutect2, varscan2
- SAE1 | c.738C>T p.L246= | Silent (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- SCN1A | c.5406G>A p.E1802= (on ENST00000303395 / NM_001202435.3; = p.E1791= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/502 reads (22%) | catalogued as rs763478023; called by muse, mutect2, varscan2
- SEMA3F | c.1053G>A p.R351= | Silent (SNP) | VAF 110/482 reads (23%) | called by muse, mutect2, varscan2
- SEMA4C | c.1746C>T p.N582= | Silent (SNP) | VAF 189/723 reads (26%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.2271C>T p.V757= | Silent (SNP) | VAF 136/500 reads (27%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1539G>A p.R513= | Silent (SNP) | VAF 76/359 reads (21%) | catalogued as COSV63037005; called by muse, mutect2, varscan2
- SHANK2 | c.3180G>A p.P1060= | Silent (SNP) | VAF 149/620 reads (24%) | catalogued as rs1565529798; called by muse, mutect2, varscan2
- SKIV2L | c.1452C>T p.P484= | Silent (SNP) | VAF 306/891 reads (34%) | catalogued as rs749486701, COSV64814704; called by muse, mutect2, varscan2
- SLC14A2 | c.1197C>T p.T399= | Silent (SNP) | VAF 99/365 reads (27%) | called by muse, mutect2, varscan2
- SLC4A10 | c.972G>A p.K324= (on ENST00000446997 / NM_001354461.2; = p.K294= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 68/306 reads (22%) | called by muse, mutect2, varscan2
- SLC8A3 | c.822C>T p.I274= | Silent (SNP) | VAF 79/519 reads (15%) | catalogued as COSV63526367; called by muse, mutect2, varscan2
- SLC9A3 | c.1926C>T p.P642= | Silent (SNP) | VAF 254/571 reads (44%) | called by muse, mutect2, varscan2
- SLIT2 | c.4512C>T p.F1504= | Silent (SNP) | VAF 125/463 reads (27%) | catalogued as rs370110126; called by muse, mutect2, varscan2
- SLIT3 | c.4107G>A p.R1369= | Silent (SNP) | VAF 100/434 reads (23%) | catalogued as COSV60606809, COSV60616265; called by muse, mutect2
- SLX4 | c.39C>T p.Y13= | Silent (SNP) | VAF 68/258 reads (26%) | called by muse, mutect2, varscan2
- SMARCA1 | c.765C>T p.V255= | Silent (SNP) | VAF 100/208 reads (48%) | called by muse, mutect2, varscan2
- SMTNL1 | c.48C>T p.S16= | Silent (SNP) | VAF 125/466 reads (27%) | called by muse, mutect2, varscan2
- SNX29 | c.114C>T p.S38= | Silent (SNP) | VAF 81/331 reads (24%) | catalogued as rs531027822; called by muse, mutect2, varscan2
- SPATA31A3 | c.1848G>A p.R616= | Silent (SNP) | VAF 346/890 reads (39%) | catalogued as rs1424126576; called by muse, mutect2, varscan2
- SPHKAP | c.2085C>T p.N695= | Silent (SNP) | VAF 126/468 reads (27%) | catalogued as COSV100763715, COSV60885204; called by muse, mutect2, varscan2
- SRRM3 | c.246G>A p.E82= | Silent (SNP) | VAF 84/474 reads (18%) | called by muse, mutect2, varscan2
- STPG1 | c.687T>C p.G229= (on ENST00000337248 / NM_001199013.2; = p.G182= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- SULT4A1 | c.483C>T p.F161= | Silent (SNP) | VAF 63/275 reads (23%) | catalogued as COSV50783487; called by muse, mutect2, varscan2
- TAC3 | c.303G>A p.T101= | Silent (SNP) | VAF 78/343 reads (23%) | catalogued as rs146110551, COSV100269884; called by muse, mutect2, varscan2
- TACC1 | c.1188C>T p.P396= | Silent (SNP) | VAF 139/424 reads (33%) | catalogued as COSV99392816; called by muse, mutect2, varscan2
- TACC2 | c.6498G>A p.G2166= (on ENST00000334433; = p.G244= on NM_006997.4) | Silent (SNP) | VAF 143/597 reads (24%) | called by muse, mutect2, varscan2
- TAF1L | c.2379G>A p.R793= | Silent (SNP) | VAF 140/735 reads (19%) | catalogued as rs375958919; called by muse, mutect2, varscan2
- TAMALIN | c.870C>T p.F290= | Silent (SNP) | VAF 68/273 reads (25%) | called by muse, mutect2, varscan2
- TANC2 | c.4548C>T p.F1516= | Silent (SNP) | VAF 143/496 reads (29%) | catalogued as rs759908687; called by muse, mutect2, varscan2
- TAS2R41 | c.162C>T p.S54= | Silent (SNP) | VAF 134/576 reads (23%) | called by muse, mutect2, varscan2
- TBC1D8 | c.2757A>T p.L919= | Silent (SNP) | VAF 62/246 reads (25%) | called by muse, mutect2, varscan2
- TENM4 | c.3813C>T p.F1271= | Silent (SNP) | VAF 64/347 reads (18%) | called by muse, mutect2, varscan2
- TEX55 | c.135C>T p.N45= | Silent (SNP) | VAF 106/403 reads (26%) | called by muse, mutect2, varscan2
- TFEB | c.201G>A p.G67= | Silent (SNP) | VAF 180/579 reads (31%) | called by muse, mutect2, varscan2
49 further variants in this file (0 protein-altering or splice-affecting, 27 silent, 22 other) are not listed here.
